Somatic mutation profile of tumor specimen TCGA-09-2055-01B (aliquot TCGA-09-2055-01B-01W-0799-08) from TCGA case TCGA-09-2055, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IC; Tumor grade: G3; Age at diagnosis: 48.0 years (17,545 days).
Specimen TCGA-09-2055-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c48d6968-ec4d-46f3-abb2-4e9d93f67e89.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-09-2055-10A (Blood Derived Normal), aliquot TCGA-09-2055-10A-01W-0799-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dcbaa95a-4539-4159-b2bc-6248f47f98b8

The open-access MAF lists 103 somatic variants for this specimen: 82 protein-altering or splice-affecting, 19 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 69, Silent 19, Nonsense Mutation 5, Frame Shift Del 3, Splice Region 2, In Frame Ins 1, Splice Site 1, 5'Flank 1, 5'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 35/53 reads (66%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCC8 | c.625G>C p.D209H | Missense Mutation (SNP) | VAF 110/242 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM085199, COSV100217364; called by muse, mutect2, varscan2
- ADD3 | c.1919A>T p.D640V (on ENST00000356080 / NM_001320591.2; = p.D608V on NM_001121.4) | Missense Mutation (SNP) | VAF 178/644 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.25); catalogued as COSV99523475; called by muse, mutect2, varscan2
- AK3 | c.406C>G p.R136G | Missense Mutation (SNP) | VAF 68/158 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63346515; called by muse, mutect2, varscan2
- ANKRD10 | c.641G>C p.R214T | Missense Mutation (SNP) | VAF 78/111 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99941154; called by muse, mutect2, varscan2
- ATG14 | c.1259G>C p.G420A | Missense Mutation (SNP) | VAF 211/567 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); catalogued as COSV99902835; called by muse, mutect2, varscan2
- BTN2A1 | c.125C>G p.T42R | Missense Mutation (SNP) | VAF 82/246 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.086); catalogued as COSV100438634; called by muse, mutect2, varscan2
- CASR | c.1753T>A p.F585I (on ENST00000490131; = p.F662I on NM_000388.4) | Missense Mutation (SNP) | VAF 209/458 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99949073; called by muse, mutect2, varscan2
- CHRNA3 | c.1282G>T p.V428F | Missense Mutation (SNP) | VAF 115/311 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.195); catalogued as COSV100468364; called by muse, mutect2, varscan2
- CKLF-CMTM1 | c.149G>C p.G50A | Missense Mutation (SNP) | VAF 14/216 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV99862613; called by muse, mutect2
- CNTNAP4 | c.427T>A p.Y143N | Missense Mutation (SNP) | VAF 460/1100 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.491); catalogued as COSV100271855, COSV56676045; called by muse, mutect2, varscan2
- CREB3L3 | c.46T>C p.S16P | Missense Mutation (SNP) | VAF 101/143 reads (71%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99314225; called by muse, mutect2, varscan2
- CSE1L | c.2029G>C p.D677H | Missense Mutation (SNP) | VAF 107/403 reads (27%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.549); catalogued as COSV99522068; called by muse, mutect2, varscan2
- CUL9 | c.1891G>A p.E631K | Missense Mutation (SNP) | VAF 44/128 reads (34%) | SIFT tolerated (0.28); PolyPhen benign (0.033); catalogued as rs201640275, COSV99335526; called by muse, mutect2, varscan2
- DCDC2B | c.483G>C p.K161N | Missense Mutation (SNP) | VAF 63/369 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.348); catalogued as COSV99356630; called by muse, mutect2, varscan2
- EFCAB13 | c.1819G>T p.E607* | Nonsense Mutation (SNP) | VAF 100/118 reads (85%) | catalogued as COSV100516638; called by muse, mutect2, varscan2
- FAT3 | c.3388T>C p.S1130P | Missense Mutation (SNP) | VAF 16/271 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.192); catalogued as COSV99967044; called by muse, mutect2
- FGFBP3 | c.10C>A p.P4T | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.108); catalogued as COSV100284638; called by muse, mutect2, varscan2
- FLG2 | c.1756G>A p.G586S | Missense Mutation (SNP) | VAF 398/1008 reads (39%) | SIFT tolerated (0.4); PolyPhen benign (0.17); catalogued as COSV101165935; called by muse, mutect2, varscan2
- FRMD7 | c.1840C>T p.P614S | Missense Mutation (SNP) | VAF 20/476 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100049073; called by muse, mutect2
- GPLD1 | c.1812T>A p.N604K | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as COSV100015395; called by muse, mutect2, varscan2
- GPR173 | c.79G>C p.V27L | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV100212293; called by muse, mutect2, varscan2
- GRM3 | c.2591C>T p.T864M | Missense Mutation (SNP) | VAF 314/828 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.939); catalogued as rs768262279, COSV64470067; called by muse, mutect2, varscan2
- H4C8 | c.47C>G p.A16G | Missense Mutation (SNP) | VAF 86/262 reads (33%) | SIFT deleterious (0); catalogued as COSV56805446, COSV56805600, COSV99175483; called by muse, mutect2, varscan2
- IDH2 | c.1144C>G p.R382G | Missense Mutation (SNP) | VAF 76/151 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99184169; called by muse, mutect2, varscan2
- IKZF5 | c.218G>A p.G73E | Missense Mutation (SNP) | VAF 237/380 reads (62%) | SIFT tolerated (0.12); PolyPhen benign (0.07); catalogued as rs1023663546, COSV100924744; called by muse, mutect2, varscan2
- INTS9 | c.161G>A p.G54D | Missense Mutation (SNP) | VAF 138/289 reads (48%) | SIFT tolerated (0.37); PolyPhen benign (0.011); catalogued as COSV101273897; called by muse, varscan2
- IRF2 | c.250G>A p.A84T | Missense Mutation (SNP) | VAF 44/63 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66928684, COSV66929319; called by muse, mutect2, varscan2
- ITPRIP | c.588G>A p.M196I | Missense Mutation (SNP) | VAF 178/349 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.437); catalogued as rs768181389, COSV53393548, COSV99532613; called by muse, mutect2, varscan2
- KIF14 | c.2327C>A p.A776D | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs903390215, COSV100950906; called by muse, mutect2
- KRT74 | c.1324T>A p.Y442N | Missense Mutation (SNP) | VAF 86/204 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99977560; called by muse, mutect2, varscan2
- LMLN | c.59C>G p.S20W | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.186); catalogued as COSV99502407, COSV99502768; called by muse, mutect2, varscan2
- LMO3 | c.330G>C p.Q110H | Missense Mutation (SNP) | VAF 18/212 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV99662824; called by muse, mutect2
- LOXL3 | c.1463G>T p.S488I | Missense Mutation (SNP) | VAF 90/154 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99239737; called by muse, mutect2, varscan2
- LPA | c.5502A>T p.Q1834H | Missense Mutation (SNP) | VAF 220/296 reads (74%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV60298048, COSV60302164, COSV60303870; called by muse, varscan2
- MAGED1 | c.2228G>A p.R743H | Missense Mutation (SNP) | VAF 66/169 reads (39%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as rs782402643, COSV58516219; called by muse, mutect2, varscan2
- MBTPS1 | c.298G>A p.D100N | Missense Mutation (SNP) | VAF 47/643 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100597644; called by muse, mutect2
- MED13 | c.5036C>G p.P1679R | Missense Mutation (SNP) | VAF 175/230 reads (76%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.511); catalogued as COSV101181141, COSV67265912; called by muse, mutect2, varscan2
- MTHFR | c.1565C>T p.A522V | Missense Mutation (SNP) | VAF 44/56 reads (79%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1255283120, COSV57171120; called by muse, mutect2, varscan2
- NEU1 | c.775G>C p.D259H | Missense Mutation (SNP) | VAF 78/121 reads (64%) | SIFT deleterious (0); PolyPhen benign (0.412); catalogued as COSV99999019; called by muse, mutect2, varscan2
- NEXN | c.1474G>T p.E492* | Nonsense Mutation (SNP) | VAF 45/91 reads (49%) | catalogued as COSV99629011; called by muse, mutect2, varscan2
- NF1 | c.3049C>T p.Q1017* | Nonsense Mutation (SNP) | VAF 82/130 reads (63%) | catalogued as CM950846, COSV62195945; called by muse, mutect2, varscan2
- NLGN3 | c.1075G>C p.E359Q (on ENST00000358741 / NM_181303.2; = p.E339Q on NM_018977.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 69/233 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV100704823; called by muse, mutect2, varscan2
- NUGGC | c.1940A>G p.H647R | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV100429354; called by muse, mutect2, varscan2
- OR11H12 | c.468T>G p.C156W | Missense Mutation (SNP) | VAF 132/1946 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101612501, COSV101612535; called by muse, mutect2
- OR7C2 | c.333C>A p.D111E | Missense Mutation (SNP) | VAF 64/178 reads (36%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.32); catalogued as COSV99934552; called by muse, mutect2, varscan2
- PASK | c.1729G>A p.G577R | Missense Mutation (SNP) | VAF 37/94 reads (39%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.564); catalogued as COSV99299620; called by muse, mutect2, varscan2
- PAX9 | c.953C>T p.P318L | Missense Mutation (SNP) | VAF 159/374 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.013); catalogued as rs372101496; called by muse, mutect2, varscan2
- PCDH15 | c.4561G>A p.D1521N | Missense Mutation (SNP) | VAF 63/156 reads (40%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0); catalogued as COSV100222153, COSV57288350; called by muse, mutect2, varscan2
- PIEZO2 | c.7028T>A p.F2343Y | Missense Mutation (SNP) | VAF 59/230 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV99555095; called by muse, mutect2, varscan2
- POU5F1 | c.923G>T p.G308V | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.188); catalogued as COSV99463083; called by muse, mutect2, varscan2
- POU6F2 | c.155C>G p.S52* | Nonsense Mutation (SNP) | VAF 45/118 reads (38%) | catalogued as COSV101302704; called by muse, mutect2, varscan2
- RCC2 | c.1029G>T p.L343= | Splice Region (SNP) | VAF 17/28 reads (61%) | catalogued as COSV100965171; called by muse, mutect2, varscan2
- RGS19 | c.113C>A p.P38H | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.533); catalogued as COSV100180766; called by muse, mutect2, varscan2
- RPAP1 | c.2232C>A p.I744= | Splice Region (SNP) | VAF 9/164 reads (5%) | catalogued as COSV100427175; called by muse, mutect2
- SDHB | c.631G>A p.V211I | Missense Mutation (SNP) | VAF 21/23 reads (91%) | SIFT tolerated (0.31); PolyPhen benign (0.145); catalogued as COSV100973445; called by muse, mutect2, varscan2
- SEMG1 | c.7C>G p.P3A | Missense Mutation (SNP) | VAF 263/425 reads (62%) | SIFT deleterious (0.04); PolyPhen benign (0.278); catalogued as COSV99725309; called by muse, mutect2, varscan2
- SF3A1 | c.2362A>G p.R788G | Missense Mutation (SNP) | VAF 185/229 reads (81%) | SIFT deleterious (0); PolyPhen benign (0.084); catalogued as COSV99305506; called by muse, mutect2, varscan2
- STAMBP | c.830G>T p.R277L | Missense Mutation (SNP) | VAF 82/186 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as COSV100277720; called by muse, mutect2, varscan2
- STAT3 | c.97T>A p.F33I | Missense Mutation (SNP) | VAF 6/140 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV52894701, COSV99232841; called by muse, mutect2
- TAF1 | c.2535G>T p.K845N (on ENST00000373790 / NM_138923.4; = p.K866N on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 245/702 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99336045; called by muse, mutect2, varscan2
- TMEM106B | c.754G>C p.D252H | Missense Mutation (SNP) | VAF 59/87 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101188830, COSV67543986; called by muse, mutect2, varscan2
- TMEM176A | c.274A>T p.T92S | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.492); catalogued as COSV99133792; called by muse, mutect2, varscan2
- TNK2 | c.2134C>T p.Q712* | Nonsense Mutation (SNP) | VAF 4/10 reads (40%) | catalogued as rs1310731001, COSV100361437; called by muse, mutect2, varscan2
- TNNC2 | c.289G>A p.A97T | Missense Mutation (SNP) | VAF 97/158 reads (61%) | SIFT deleterious (0.04); PolyPhen benign (0.113); catalogued as rs1200344426, COSV100999456; called by muse, mutect2, varscan2
- TNPO2 | c.57C>G p.D19E | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100790371; called by muse, mutect2, varscan2
- TNPO3 | c.724C>A p.H242N | Missense Mutation (SNP) | VAF 56/1208 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV99603062; called by muse, mutect2
- TTC7A | c.2266G>A p.E756K | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.602); catalogued as rs754721168, COSV99766539; called by muse, varscan2
- UBR4 | c.7400C>T p.P2467L | Missense Mutation (SNP) | VAF 220/323 reads (68%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV100921071; called by muse, mutect2, varscan2
- VSTM1 | c.518C>T p.T173I | Missense Mutation (SNP) | VAF 140/185 reads (76%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV100618811; called by muse, mutect2, varscan2
- WHRN | c.1020C>A p.D340E | Missense Mutation (SNP) | VAF 204/273 reads (75%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.941); catalogued as COSV99470347; called by muse, mutect2, varscan2
- ZBTB44 | c.1036G>A p.V346I | Missense Mutation (SNP) | VAF 43/123 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as rs1028585105, COSV63537729; called by muse, mutect2, varscan2
- ZKSCAN2 | c.1555G>A p.E519K | Missense Mutation (SNP) | VAF 58/153 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.565); catalogued as COSV100048271; called by muse, mutect2, varscan2
- ZNF638 | c.196C>T p.P66S | Missense Mutation (SNP) | VAF 178/517 reads (34%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.996); catalogued as COSV100039066; called by muse, mutect2, varscan2
- ZP4 | c.1491G>T p.K497N | Missense Mutation (SNP) | VAF 54/140 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV100850702; called by muse, varscan2
- AHCTF1 | c.4235_4237+7del p.X1412_splice (on ENST00000366508; = p.X1386_splice on NM_015446.5) | Splice Site (DEL) | VAF 34/121 reads (28%) | called by mutect2, pindel, varscan2
- LRIF1 | c.276_284dup p.V93_L95dup | In Frame Ins (INS) | VAF 120/410 reads (29%) | called by mutect2, varscan2
- LRRC4 | c.429_462del p.E144Afs*47 | Frame Shift Del (DEL) | VAF 34/62 reads (55%) | called by mutect2, pindel
- NPHP3 | c.105del p.K35Nfs*114 | Frame Shift Del (DEL) | VAF 4/14 reads (29%) | called by mutect2, varscan2
- SHPRH | c.4121C>A p.P1374Q (on ENST00000275233 / NM_001042683.3; = p.P1378Q on NM_173082.3) | Missense Mutation (SNP) | VAF 20/654 reads (3%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.818); called by muse, mutect2
- TNRC6B | c.354_375del p.G119Pfs*14 | Frame Shift Del (DEL) | VAF 11/44 reads (25%) | called by mutect2, pindel
- UBR5 | c.3203_3214del p.G1068_T1071del | In Frame Del (DEL) | VAF 38/279 reads (14%) | called by mutect2, pindel, varscan2
- AKAP8L | c.702G>A p.Q234= | Silent (SNP) | VAF 42/149 reads (28%) | catalogued as COSV101275807; called by muse, mutect2, varscan2
- CHTOP | c.126G>A p.Q42= | Silent (SNP) | VAF 91/172 reads (53%) | catalogued as rs1557938691, COSV100904683; called by muse, mutect2, varscan2
- CIPC | c.474T>C p.N158= | Silent (SNP) | VAF 46/93 reads (49%) | catalogued as COSV100694473; called by muse, mutect2, varscan2
- CTDSP1 | c.415C>T p.L139= | Silent (SNP) | VAF 15/50 reads (30%) | catalogued as rs903304393, COSV99811993, COSV99812011; called by muse, mutect2
- DENND4C | c.729C>T p.C243= | Silent (SNP) | VAF 75/215 reads (35%) | catalogued as COSV100991386; called by muse, mutect2
- DNAH5 | c.4461C>T p.A1487= | Silent (SNP) | VAF 9/134 reads (7%) | catalogued as COSV99450759; called by muse, mutect2
- EFL1 | c.126C>T p.S42= | Silent (SNP) | VAF 71/191 reads (37%) | catalogued as rs758970278, COSV99187341; called by muse, mutect2, varscan2
- HR | c.2751C>T p.F917= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as COSV100455866; called by muse, mutect2
- ITGA1 | c.3156C>T p.D1052= | Silent (SNP) | VAF 76/185 reads (41%) | catalogued as COSV99251549; called by muse, mutect2, varscan2
- LRRTM2 | c.324A>C p.L108= | Silent (SNP) | VAF 27/93 reads (29%) | catalogued as COSV99217810; called by muse, mutect2, varscan2
- LSMEM2 | c.426C>A p.L142= | Silent (SNP) | VAF 10/20 reads (50%) | catalogued as rs1553708697, COSV100269579; called by muse, mutect2, varscan2
- NUGGC | c.1941C>T p.H647= | Silent (SNP) | VAF 19/51 reads (37%) | catalogued as rs1036866086, COSV100429351; called by muse, mutect2, varscan2
- OBSL1 | c.2043C>T p.L681= | Silent (SNP) | VAF 10/71 reads (14%) | catalogued as rs1559152424, COSV99216981; called by muse, varscan2
- OR4Q3 | c.507C>A p.V169= | Silent (SNP) | VAF 100/413 reads (24%) | catalogued as COSV100057116; called by muse, mutect2, varscan2
- PCDH11X | c.123C>T p.G41= | Silent (SNP) | VAF 65/177 reads (37%) | catalogued as COSV53456219, COSV53461674; called by muse, mutect2, varscan2
- PIM2 | c.72T>C p.D24= | Silent (SNP) | VAF 14/29 reads (48%) | catalogued as COSV99332045; called by muse, mutect2, varscan2
- SLC9A4 | c.732T>C p.N244= | Silent (SNP) | VAF 18/58 reads (31%) | catalogued as rs143655953; called by muse, mutect2
- SNX13 | c.210A>G p.T70= | Silent (SNP) | VAF 19/43 reads (44%) | catalogued as COSV101285119; called by muse, mutect2, varscan2
- TTLL8 | c.906G>A p.E302= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as COSV99838415; called by muse, mutect2
- CTBP1 | chr4:1250934 C>G | 5'Flank (SNP) | VAF 5/27 reads (19%) | called by muse, mutect2, varscan2
- OR2W1 | c.-2C>G | 5'UTR (SNP) | VAF 79/285 reads (28%) | catalogued as COSV101013919; called by muse, mutect2, varscan2
